TARGET case TARGET-50-PAJNJL — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/252fdd80-b599-546f-b0fd-88e6e7c9a4f4

Demographics
Sex at birth: female; Age at index: 9 years; Vital status: Dead; Days to death: 463 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 9.2 years (3,367 days); Year of diagnosis: 1999; Days to last follow up: 463 days (1.3 years); Pediatric kidney staging: Nephrectomy specimen with tumor confined to the kidney, no distant metastasis; Wilms tumor histologic subtype: Unfavorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 125 days; Days to first event: 125 days; First event: Relapse.
- Days to follow up: 463 days (1.3 years); Year of follow up: 2000.

Biospecimens (1 sample)
- Sample TARGET-50-PAJNJL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJNJL-01A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: Yes
- % Tumor Nuclei: Top: 10
- % Non tumor Nuclei: Top: 90
- % Cellular Tumor: Top: 5
- % Normal: Top: 0
- % Stroma: Top: 48
- % Necrosis: Top: 47
- % Tumor Nuclei: Bottom: 10
- % Non tumor Nuclei: Bottom: 90
- % Cellular Tumor: Bottom: 5
- % Normal: Bottom: 0
- % Stroma: Bottom: 48
- % Necrosis: Bottom: 47
- Pathology Pass/Fail: Fail

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJNJL-01A-02:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 10
- % Non tumor Nuclei: Top: 90
- % Cellular Tumor: Top: 5
- % Normal: Top: 0
- % Stroma: Top: 90
- % Necrosis: Top: 5
- % Tumor Nuclei: Bottom: 10
- % Non tumor Nuclei: Bottom: 90
- % Cellular Tumor: Bottom: 5
- % Normal: Bottom: 0
- % Stroma: Bottom: 90
- % Necrosis: Bottom: 5
- Pathology Pass/Fail: fail

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 463
- Stage: I
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: DAWT
